Gene-level copy-number profile of tumor specimen C3L-08245-01 (profiled together with C3L-08245-02) from CPTAC case C3L-08245, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 77.0 years (28,133 days).
Specimen C3L-08245-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Fundus Of Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 81d66517-a2bc-44b9-bc46-e05b2ff37ab2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-08245-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,730 have no estimate.
https://portal.gdc.cancer.gov/files/284d04ba-fccf-4e55-a878-9d7e4336792e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 468; copy number 1: 7,485; copy number 2: 26,293; copy number 3: 18,421; copy number 4: 4,149; copy number 5: 1,519; copy number 6: 318; copy number 7: 32; copy number 8: 129; copy number 9: 47; copy number 10: 22; copy number 11: 2; copy number 12: 8.

Homozygous deletions (total copy number 0; autosomes only): 111 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:13,892,792–15,118,043, 1 gene (within-gene range 0–2): KAZN.
- chr1:14,692,129–14,777,727, 2 genes: TBCAP2, AL031293.1.
- chr2:14,530,941–14,531,223, 1 gene: Metazoa_SRP.
- chr2:232,878,701–233,035,057, 3 genes (within-gene range 0–2): NGEF, AC106876.1, NEU2.
- chr3:30,606,601–30,694,142, 2 genes: TGFBR2, AC096921.1.
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr4:90,370,123–90,370,427, 1 gene (within-gene range 0–1): RN7SKP248.
- chr4:170,481,695–170,482,195, 1 gene: AC074255.1.
- chr4:181,260,442–181,265,145, 1 gene: LINC02500.
- chr5:59,039,761–59,063,503, 1 gene (within-gene range 0–1): AC092343.1.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr6:99,082,449–99,175,479, 3 genes: AL078603.1, MIR548AI, BDH2P1.
- chr6:138,402,585–138,692,571, 6 genes (within-gene range 0–2): MARCKSL1P2, HEBP2, NHSL1, MIR3145, AL391669.1, AL590617.1.
- chr6:158,921,271–158,926,571, 2 genes: AL627422.1, RNU6-293P.
- chr7:497,258–525,238, 2 genes: PDGFA, HRAT92.
- chr10:38,601,418–38,605,609, 1 gene: ABCD1P2.
- chr10:87,994,618–90,628,852, 55 genes: AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2, AL157394.1, MIR4679-2, MIR4679-1, AL513533.1, CH25H, LIPA, IFIT2, AL353751.1, IFIT3, IFIT6P, IFIT1B, IFIT1, IFIT5, SLC16A12, SLC16A12-AS1, PANK1, MIR107, AL157400.5, AL157400.2, AL157400.1, AL157400.3, AL157400.4, KIF20B, LINC00865, MARK2P16, LINC01374, LINC01375, SNRPD2P1, AL139340.1, RN7SKP143, LINC02653, AL391704.1, AL391704.2.
- chr14:61,681,041–61,695,823, 1 gene (within-gene range 0–1): HIF1A-AS1.
- chr14:67,189,393–67,336,061, 4 genes (within-gene range 0–1): FAM71D, SF3B4P1, MPP5, AL135978.1.
- chr22:18,400,407–18,530,573, 8 genes: PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,077 genes in 71 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:234,604,269–234,980,804, 15 genes, copy number 8: IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3.
- chr1:248,361,581–248,937,043, 35 genes, copy number 5: OR2T4, OR2T6, OR2T1, OR2T7, OR2T2, OR2T3, AC138089.1, OR2T5, OR2AS2P, OR2G6, AC098483.1, OR2AS1P, OR2T29, OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35, OR2T27, CR589904.2, OR14I1, LYPD9P, CR589904.1, AHCYP8, LYPD8, DPY19L4P1, SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P, RPL23AP25.
- chr2:90,082,635–91,685,884, 22 genes, copy number 5–6: IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1, LSP1P4, RNA5SP100, DRD5P1.
- chr3:88,051,944–90,184,733, 17 genes, copy number 5: CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P.
- chr4:169,094,259–170,372,311, 20 genes, copy number 5: SH3RF1, RPL6P12, AC096741.1, NEK1, AC084724.1, CLCN3, HPF1, PTGES3P3, AC079768.1, AC079768.4, LINC02275, AC079768.2, AC084866.2, AC084866.1, MFAP3L, AADAT, APOBEC3AP1, AC069306.1, LINC01612, LINC02512.
- chr5:9,546,200–32,444,740, 290 genes, copy number 5 (broad region; genes not listed).
- chr7:56,805,336–57,610,104, 40 genes, copy number 5: CICP28, AC118758.2, AC118758.1, AC069152.1, MIR4283-1, TNRC18P3, SLC29A4P1, PHKG1P4, AC122133.1, ZNF479, AC099654.11, AC099654.2, MTATP6P8, MTCO3P10, MTND4LP32, MTND4P4, MTND5P6, MTCYBP29, GUSBP10, MTND1P4, MTND2P6, MTCO1P10, MTCO2P10, MTCO3P4, AC099654.7, MTND4P5, MTND5P7, MTCYBP5, GUSBP12, AC099654.1, RNU7-157P, AC099654.3, AC237221.2, AC237221.1, MIR3147, VN1R28P, SAPCD2P2, ZNF716, AC092175.1, NCOR1P3.
- chr7:148,438,309–159,233,377, 231 genes, copy number 5 (broad region; genes not listed).
- chr8:65,526,738–67,746,378, 46 genes, copy number 8: LINC01299, AC100814.1, Y_RNA, ARMC1, MTFR1, AC055822.1, PDE7A, AC100812.1, DNAJC5B, AC084082.1, TRIM55, CRH, LINC00967, AC009879.4, RRS1-AS1, RRS1, AC009879.2, AC009879.3, ADHFE1, AC009879.1, VXN, RNU6-1324P, MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1, COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1, CPA6, NACAP10, AC022874.1.
- chr8:69,987,415–71,228,629, 19 genes, copy number 5 (within-gene range 3–5): SUMO2P20, PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1, TRAM1, LACTB2-AS1, LACTB2, RN7SL19P, XKR9, AC015687.1, Y_RNA.
- chr8:79,611,117–84,921,844, 81 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr8:92,882,984–94,793,836, 48 genes, copy number 5–6: AC117834.1, TRIQK, IRF5P1, MIR8084, C8orf87, LINC00535, AC016885.1, AC016885.3, AC016885.2, RNA5SP274, ZNF317P1, CIBAR1, AC120053.1, AC010834.3, RBM12B, AC010834.1, RBM12B-AS1, AC010834.2, TMEM67, AC084346.1, MYL12AP1, PDP1, MIR378D2HG, MIR378D2, PSMA2P2, RPL34P18, AC105081.1, AP003351.1, CDH17, AP003478.1, GEM, RPS4XP10, RAD54B, FSBP, VIRMA, AC023632.5, AC023632.2, AC023632.1, AC023632.3, AC023632.4, AC108860.2, ESRP1, Metazoa_SRP, AC108860.1, AP005660.1, Y_RNA, DPY19L4, AP003692.1.
- chr8:99,527,826–100,663,415, 29 genes, copy number 5: Y_RNA, MIR599, MIR875, RN7SL350P, AC018442.1, AC018442.2, AC018442.3, COX6C, AC105328.1, RGS22, SNORD77B, AC021590.1, FBXO43, POLR2K, SPAG1, Y_RNA, AC025647.1, Y_RNA, RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2, ANKRD46, GAPDHP62, SNX31, AP001205.1.
- chr8:102,923,371–103,501,895, 25 genes, copy number 5 (within-gene range 4–5): RPL5P24, Y_RNA, NPM1P52, AP003550.1, ATP6V1C1, MTND1P5, MTCO1P4, MTCO2P4, LINC01181, BAALC-AS2, BAALC, BAALC-AS1, MIR3151, AC025370.1, FZD6, AC025370.2, CTHRC1, AC012213.3, RNU6-1011P, SLC25A32, AC012213.5, DCAF13, AC012213.2, AC012213.4, AC012213.1.
- chr8:107,857,589–108,787,594, 13 genes, copy number 5–6: AC025508.1, RNA5SP275, RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1.
- chr8:116,642,130–118,111,826, 16 genes, copy number 5–6: EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16, EXT1.
- chr8:118,923,557–119,712,145, 16 genes, copy number 5–6: TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153.
- chr8:121,954,640–123,042,302, 15 genes, copy number 6 (within-gene range 3–6): AC037486.1, MRPS36P3, SMILR, LINC01151, AC108136.1, AC100872.1, AC100872.2, CDK5P1, AC016405.3, AC016405.2, ZHX2, AC016405.1, AC104316.2, AC104316.1, DERL1.
- chr8:123,192,875–125,367,120, 58 genes, copy number 5–8 (within-gene range 3–8): AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1, ATAD2, RNU6-875P, MIR548AA1, MIR548D1, DUTP2, IMPDH1P6, NTAQ1, U4, FBXO32, AC090193.1, RN7SKP155, AC135166.1, KLHL38, ANXA13, FAM91A1, FER1L6, AC090753.1, FER1L6-AS1, AC100871.2, FER1L6-AS2, AC100871.1, ARF1P3, AC090921.1, RNU6-756P, AC090192.2, AC090192.1, TMEM65, TRMT12, RNF139-AS1, RNF139, TATDN1, AC090198.1, MIR6844, NDUFB9, MTSS1, AC100858.2, MIR4662B, MIR4662A, LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1, NSMCE2, RN7SL329P.
- chr8:125,430,358–128,220,803, 43 genes, copy number 5–8: TRIB1, AC091114.1, AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226.
- chr8:133,191,039–134,713,049, 26 genes, copy number 5 (within-gene range 3–5): CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2, AC105180.2, AC105180.1, ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3.
- chr8:142,212,080–142,786,539, 21 genes, copy number 5 (within-gene range 3–5): TSNARE1, RN7SL260P, AC134682.1, ADGRB1, MROH4P, ARC, AP006547.1, AC108002.2, JRK, PSCA, LY6K, LNCOC1, THEM6, AC108002.1, SLURP1, LYPD2, AC083841.1, LYNX1-SLURP2, SLURP2, LYNX1, LY6D.
- chr9:110,190,048–113,119,928, 56 genes, copy number 6: C9orf152, TXN, TXNDC8, SVEP1, RNU6-1039P, AL592463.1, MUSK, AL513328.1, LPAR1, RNU6-432P, Y_RNA, RNY4P18, AL162414.1, MIR7702, OR2K2, ECPAS, RNA5SP294, ZNF483, PTGR1, AL135787.1, LRRC37A5P, DNAJC25, DNAJC25-GNG10, GNG10, SHOC1, AL354877.1, RNU6-1013P, UGCG, MIR4668, RNU6-710P, AL138756.1, SUSD1, RNU6-855P, Y_RNA, AL158824.1, PTBP3, RN7SL57P, RNA5SP295, RN7SL430P, HSPE1P28, AL359073.1, HSDL2, C9orf147, KIAA1958, AL445187.1, INIP, AL390067.1, SNX30, SLC46A2, AL139041.1, ZNF883, MUPP, ZNF883, ZFP37, FAM225B, FAM225A.
- chr9:115,019,575–127,408,424, 180 genes, copy number 5 (broad region; genes not listed).
- chr9:136,612,024–136,946,975, 38 genes, copy number 5: LINC01451, AL590226.1, EGFL7, MIR126, AGPAT2, DIPK1B, SNHG7, SNORA17B, SNORA17B, SNORA17A, AL355987.6, AL355987.5, LCN10, AL355987.1, LCN6, MIR6722, LCN8, LCN15, ATP6V1G1P3, TMEM141, AL355987.3, CCDC183, AL355987.4, AL355987.2, CCDC183-AS1, RABL6, NCLP1, MIR4292, AJM1, PHPT1, MAMDC4, EDF1, TRAF2, MIR4479, AL807752.1, AL807752.5, FBXW5, C8G.
- chr12:20,695,332–22,618,868, 35 genes, copy number 5 (within-gene range 4–5): SLCO1C1, SLCO1B3, SLCO1B3-SLCO1B7, AC011604.1, SLCO1B7, AC022335.1, SLCO1B1, SLCO1A2, IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2, LDHB, AC010197.1, AC010185.1, KCNJ8, ABCC9, AC008250.1, AC008250.2, AC092862.1, CMAS, ST8SIA1, AC007671.1, SULT6B2P, RNU1-149P, AC087318.1, AC053513.1, C2CD5, AC053513.2, LRRC34P1, AC087241.1.
- chr12:25,108,289–25,648,579, 12 genes, copy number 5 (within-gene range 4–5): CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1.
- chr12:29,337,352–30,492,302, 13 genes, copy number 5 (within-gene range 4–5): ERGIC2, OVCH1-AS1, OVCH1, TMTC1, AC009320.1, RPL21P99, AC023511.2, AC023511.1, LINC02386, AC078776.2, RNA5SP356, AC078776.1, AC026371.1.
- chr14:18,333,726–18,633,634, 12 genes, copy number 5–8 (within-gene range 4–8): CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297.
- chr15:55,826,922–56,629,592, 15 genes, copy number 5: NEDD4, CNOT6LP1, RN7SL568P, CD24P2, RFX7, AC084783.1, TEX9, AC068726.1, RNU6-1287P, HMGB1P33, AC084782.1, AC084782.2, MNS1, AC084782.3, AC090518.1.
- chr15:62,827,675–64,381,440, 32 genes, copy number 5 (within-gene range 3–5): AC103740.1, AC103740.2, AC079328.1, TPM1, TPM1-AS, AC079328.2, AC087612.1, LACTB, RPS27L, RAB8B, APH1B, CA12, LINC02568, AC007950.1, AC007950.2, USP3, USP3-AS1, FBXL22, HERC1, AC073167.1, MIR422A, AC015914.2, DAPK2, AC015914.1, CIAO2A, SNX1, Y_RNA, SNX22, PPIB, CSNK1G1, AC087632.2, AC087632.1.
- chr15:66,278,498–71,783,383, 112 genes, copy number 5–10 (within-gene range 1–10) (broad region; genes not listed).
- chr15:84,980,440–85,794,925, 25 genes, copy number 5: PDE8A, AC044860.2, AC044860.1, NIFKP8, CSPG4P12, RN7SL428P, GOLGA6L3, ADAMTS7P4, AC044860.3, AKAP13, MIR7706, RNU7-79P, FABP5P9, AC087286.3, AC087286.2, AC087286.1, RNU6-1280P, AC087286.4, AC021739.3, AC021739.2, AC021739.4, LINC02883, KLHL25, MIR1276, AC021739.1.
- chr15:89,243,945–89,951,345, 35 genes, copy number 9: FANCI, POLG, MIR6766, AC124068.2, AC133637.1, AC133637.2, MIR9-3HG, MIR9-3, RHCG, LINC00928, AC013391.3, AC013391.2, TICRR, AC013391.1, KIF7, PLIN1, PEX11A, RPL36AP43, WDR93, AC079075.1, RNU6-132P, MESP1, MRPL15P1, MESP2, ANPEP, AP3S2, ARPIN-AP3S2, MIR5094, AC027176.2, MIR5009, RNU6-1111P, ARPIN, RNU7-111P, AC027176.1, AC027176.3.
- chr15:92,393,881–94,600,821, 47 genes, copy number 5–7: ST8SIA2, AC090985.1, ENO1P2, AC090985.2, C15orf32, LINC00930, AC091544.2, AC091544.4, AC091544.5, FAM174B, AC091544.3, AC091544.7, AC091544.6, HMGN1P38, H2AZ2P1, AC091544.1, AC106028.1, AC106028.3, ASB9P1, AC106028.2, AC106028.4, CHASERR, AC013394.1, CHD2, MIR3175, RGMA, YBX2P2, AC091078.1, AC112693.1, AC112693.2, AC091078.2, SEPHS1P2, AC110023.1, LINC01579, AC103996.1, LINC02207, AC103996.3, AC103996.2, LINC01580, LINC01581, AC104390.1, H3P40, MCTP2, AC135626.1, AC135626.2, AC009432.2, AC009432.1.
- chr15:95,990,582–96,842,384, 27 genes, copy number 5: AC012409.2, AC024337.1, AC024337.2, NR2F2-AS1, AC012409.5, AC012409.3, AC012409.1, AC012409.4, LINC02157, AC016251.1, NR2F2, MIR1469, AC103746.1, AC087477.2, TUBAP12, AC087477.5, AC087477.3, PGAM1P12, AC087477.1, AC087477.4, RN7SKP254, Metazoa_SRP, AC110588.1, FAM149B1P1, SPATA8-AS1, SPATA8, RN7SKP181.
- chr16:46,469,341–46,790,407, 13 genes, copy number 5 (within-gene range 3–5): ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3.
- chr18:20,946,906–24,544,154, 86 genes, copy number 5–12 (broad region; genes not listed).
- chr19:4,675,224–5,153,598, 15 genes, copy number 6: DPP9, DPP9-AS1, AC005594.1, MIR7-3HG, MIR7-3, AC005523.1, FEM1A, AC005523.2, TICAM1, AC027319.1, PLIN3, ARRDC5, UHRF1, MIR4747, KDM4B.
- chr19:30,228,290–33,927,625, 69 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,840. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
